Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A3OK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A3OK-01A (Primary Tumor).

[page 1 of 4]
p.o. appt

100-0-3

carcinoma, serous, NOS 8441/3
Site: Endometrium C54.1

lw 2/2/12

NAME: [REDACTED]
DOB: [REDACTED]
SEX: F
AGE: [REDACTED]
ROOM #: [REDACTED]

MR#: [REDACTED] ACCT#: [REDACTED]
PT CLASS: [REDACTED]
CLINIC CODE: [REDACTED]
ADMIT DATE: [REDACTED]
DISCH DATE: [REDACTED] RPT: [REDACTED]

ATTENDING PHYSICIAN: [REDACTED]
ADMITTING PHYSICIAN: [REDACTED]

SURGERY CASE #: [REDACTED]

SURGERY CASE #: [REDACTED] FINAL

Reviewed

DATE OF SURGERY: [REDACTED]

SURGEON: [REDACTED]

Disposition

SPECIMEN:

- A. Pelvic washing with 1000 units of Heparin.
- B. Uterus, cervix, tubes and ovaries.
- C. Right pelvic lymph nodes.
- D. Right periaortic lymph nodes.
- E. Left pelvic lymph nodes.

FROZEN SECTION DIAGNOSIS: B. Endometrioid adenocarcinoma.
No definite myometrial invasion on frozen section.
Endocervix grossly benign.

OPERATIVE PROCEDURE: Total laparoscopic hysterectomy, bilateral salpingo-oophorectomy, lymph node dissection/staging.

PREOPERATIVE DIAGNOSIS: Endometrial cancer.

POSTOPERATIVE DIAGNOSIS: Pending pathology.

*****DIAGNOSIS*****

1. Type of Specimen and Procedure:
Uterus, cervix, right and left fallopian tubes and ovaries, regional lymph nodes, and pelvic washings;
Total laparoscopic hysterectomy, bilateral salpingo-oophorectomy and staging lymph node dissection.
2. Tumor Type:
Serous papillary carcinoma of endometrium.
3. Grade: High grade by definition
4. Depth of Invasion:
The tumor invades the myometrium to a depth of 2 mm.
A. The thickness of the myometrium in the area of maximum tumor invasion is 10 mm.
5. Lymphovascular Space Involvement: Not identified.

Surgical Pathology Consultation
Page 1 of 4
PHYSICIAN COPY

Case is Circled		
Reviewed with		

lw 2/2/12

1/30/12

[page 2 of 4]
NAME:

DOB:

SEX: F

AGE:

ROOM #: [REDACTED]

MR#:

PT CLASS:

CLINIC CODE:

ADMIT DATE:

DISCH DATE:

ACCT#:

RPT: [REDACTED]

ATTENDING PHYSICIAN:

ADMITTING PHYSICIAN:

SURGERY CASE #:

6. Extent:

- A. Endocervical involvement: negative.
- B. Paracervical tissue involvement: negative.
- C. Uterine serosa: negative.
- D. Fallopian tubes and ovaries: negative.

Margins: Negative.

8. Lymph Nodes: Negative.

14 right pelvic lymph nodes, no malignancy found (0/14).
3 right periaortic lymph nodes, no malignancy found (0/3).
7 left pelvic lymph nodes, no malignancy found (0/7).
Total 0/24.

9. Other Sites of Neoplastic Involvement:

None.

10. Tissue Submitted for Estrogen and Progesterone Receptor Assay; Results to be Reported Separately by [REDACTED] (Block B5).

11. Tumor Size:

The tumor measures 3 x 2 cm.

12. Tumor Site:

Anterior and posterior endometrium.

13. Additional Findings:

- 1. Cervix with atrophy. (entire cervix examined and intradepartmental consultation obtained.)
- 2. Cervix with endometriosis.
- 3. Ovarian fibromas bilateral.
- 4. Fallopian tubes with paratubal cysts.
- 5. Pelvic washings: negative.

14. Tumor Immunohistochemical Stains:

P53: Diffuse strong nuclear staining.

15. TNM STAGING:

pT1a: Tumor involves less than one-half of myometrium.
pN0: No regional lymph node metastasis.

Surgical Pathology Consultation

Page 2 of 4

PHYSICIAN COPY

[page 3 of 4]
NAME:

DOB:

SEX:

AGE:

ROOM #:

MR#:

PT CLASS:

CLINIC CODE:

ADMIT DATE:

DISCH DATE:

ACCT#:

RPT#:

ATTENDING PHYSICIAN:

ADMITTING PHYSICIAN:

SURGERY CASE #:

pMX: The metastasis cannot be assessed.

- A.
- B.
- C.
- D.

MICROSCOPIC EXAMINATION:

A-E. A microscopic examination was performed to render the above diagnosis. [REDACTED]

GROSS:

- A. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "pelvic washing with 1000 units of Heparin." It consists of approximately 25 cc of yellow watery fluid. Two cytospins are obtained. [REDACTED]
- B. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "uterus, cervix, tubes and ovaries." It consists of a hysterectomy and bilateral salpingo-oophorectomy specimen weighing 62 grams. The uterus measures 6.8 x 5 x 2.5 cm and is in continuity with the right 2.5 x 1.5 x 1 cm, and left, 3 x 1.3 x 1 cm ovaries, and the fimbriated right and left fallopian tubes, each 8 x 0.5 cm.

The entire anterior endometrial cavity is filled with a 3 x 2 cm tumor. The tumor is friable and protrudes up to 1.6 cm above the flat endometrial surface. Detached aggregates of tumor are found within the endocervical canal. Further, there is no grossly apparent extension into mucosa or underlying endocervical stroma. There is suggestion of minimal superficial invasion into underlying myometrium which measures 1.1 cm in thickness. The adnexa are grossly free of tumor. Solid fibrous nodules measuring up to 0.8 cm in largest diameter are found growing on both ovarian surfaces. Paratubal cysts are present bilaterally.

Sections:

#1 - Endometrium myometrium with tumor for frozen section, frozen section permanent. Touch preparations are obtained.

#2 - Paracervical tissue and ectocervical margins.

#3 through #6 - Tumor, full thickness, myometrium.

#7 - Random posterior endometrium myometrium.

#8 and #9 - Endocervical canal, anterior and posterior walls, respectively.

Surgical Pathology Consultation

Page 3 of 4

PHYSICIAN COPY

[page 4 of 4]
NAME:
DOB:
SEX: F
AGE:
ROOM #:

MR#:
PT CLASS:
CLINIC CODE:
ADMIT DATE:
DISCH DATE:

ACCT#:

RPT: [REDACTED]

ATTENDING PHYSICIAN:
ADMITTING PHYSICIAN:

SURGERY CASE #:

#10 and #11 - Right and left adnexa, respectively.

Sections:

+1 - Tangential ectocervical margins.

+2 through +8 - Remainder of the cervix, submitted in its entirety.

[REDACTED]

- C. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "right pelvic lymph nodes." It consists of fibroadipose tissue fragments with lymph nodes, in aggregate 6.9 x 6.1 x 1.3 cm. The lymph nodes range in size from 0.2 to 2.9 cm and appear grossly unremarkable. The lymph nodes are submitted in two cassettes.
- D. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "right periaortic lymph nodes." It consists of fibroadipose tissue fragments with lymph nodes, in aggregate 3.8 x 4.2 x 1.3 cm. The lymph nodes range in size from 0.9 to 3.4 cm and appear grossly unremarkable. The lymph nodes are submitted in a single cassette.
- E. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "left pelvic lymph nodes." It consists of fibroadipose tissue fragments with lymph nodes, in aggregate 7.3 x 5.2 x 1.4 cm. The lymph nodes range in size from 0.4 to 3.3 cm and appear grossly unremarkable. The lymph nodes are submitted in two cassettes.

Electronically Signed by

[REDACTED]

[REDACTED]

Distribution:

Dictating Physician:

Dictated: Job #

Transcribed:

Printed:

on

Surgical Pathology Consultation

Page 4 of 4

PHYSICIAN COPY

Source: NCI Genomic Data Commons file 0e3ca017-9a58-4d3e-b695-d0b1fcae31a1 (TCGA-AJ-A3OK.54D4BBBE-D458-44B2-8F7C-0185DD16D961.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).